Somatic mutation profile of tumor specimen TARGET-30-PALNLU-01A (aliquot TARGET-30-PALNLU-01A-01W) from TARGET case TARGET-30-PALNLU, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 3.9 years (1,439 days).
Specimen TARGET-30-PALNLU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d9162de-6354-4b01-ace4-38a851d74611.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALNLU-10A (Blood Derived Normal), aliquot TARGET-30-PALNLU-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b3a1f5c-b9ca-457e-8bb6-cb30ab324b2c

The open-access MAF lists 65 somatic variants for this specimen: 52 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 8, Nonsense Mutation 4, Intron 3, Splice Site 2, Frame Shift Del 2, Splice Region 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 29/119 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994087, CM085230, COSV66555567, COSV66558183; ClinVar: pathogenic / likely pathogenic /  risk factor; called by muse, mutect2, varscan2
- ABHD15 | c.1226T>G p.L409W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56195750; called by muse, mutect2, varscan2
- ACADSB | c.275C>A p.S92* | Nonsense Mutation (SNP) | VAF 50/275 reads (18%) | catalogued as COSV62550401, COSV62550904; called by muse, mutect2, varscan2
- ACKR3 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 21/101 reads (21%) | catalogued as COSV56022294; called by muse, mutect2, varscan2
- ADAM22 | c.2577-2A>C p.X859_splice (on ENST00000265727 / NM_001324420.2; = p.X823_splice on NM_016351.6 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 37/190 reads (19%) | catalogued as COSV55980019; called by muse, mutect2, varscan2
- ADAM30 | c.16A>G p.I6V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV65561359; called by muse, mutect2, varscan2
- ADGRF2 | c.1363G>A p.G455S (on ENST00000296862 / NM_001368115.2; = p.G387S on NM_153839.7) | Missense Mutation (SNP) | VAF 104/577 reads (18%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.782); catalogued as COSV57286252; called by muse, mutect2, varscan2
- AGAP1 | c.2213G>A p.R738Q (on ENST00000304032 / NM_001037131.3; = p.R685Q on NM_014914.5) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as rs534251010, COSV58329354; called by muse, mutect2, varscan2
- ANK3 | c.11180C>T p.S3727F | Missense Mutation (SNP) | VAF 109/514 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV55063413; called by muse, mutect2, varscan2
- ARID1A | c.3416G>T p.G1139V | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61372185; called by muse, mutect2, varscan2
- CDH18 | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV56930316; called by muse, mutect2, varscan2
- CR1L | c.1017C>A p.S339R | Missense Mutation (SNP) | VAF 111/656 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.364); catalogued as rs1178627321, COSV54327415, COSV54329047; called by muse, mutect2, varscan2
- DNAJC9 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 18/96 reads (19%) | catalogued as COSV54352353; called by muse, mutect2, varscan2
- DOCK5 | c.3525G>T p.L1175= | Splice Region (SNP) | VAF 31/154 reads (20%) | catalogued as COSV52404079; called by muse, mutect2, varscan2
- DOCK5 | c.4037C>A p.A1346D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52395508, COSV52404091; called by muse, mutect2
- DTWD2 | c.727-1G>T p.X243_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100407052; called by muse, mutect2
- ECT2L | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV62885294; called by muse, mutect2, varscan2
- FA2H | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs1230476289; called by muse, mutect2
- FLG | c.9732G>T p.Q3244H | Missense Mutation (SNP) | VAF 129/491 reads (26%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.76); catalogued as rs778326283, COSV64243168, COSV64243866; called by muse, mutect2, varscan2
- GPD2 | c.860T>C p.I287T | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV60093575; called by muse, mutect2, varscan2
- GRM3 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 71/510 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64473672; called by muse, mutect2, varscan2
- GUCY1A2 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as COSV56490277; called by muse, mutect2, varscan2
- HTT | c.8439C>A p.N2813K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV61861828, COSV61863843; called by muse, mutect2, varscan2
- IGFL3 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 55/271 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1237755541, COSV58242873; called by muse, varscan2
- KCNA4 | c.911G>A p.S304N | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as COSV60253380; called by muse, mutect2, varscan2
- KLF4 | c.1343G>C p.R448P | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65929108; called by muse, mutect2, varscan2
- KRT71 | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs769416296, COSV57291213; called by muse, mutect2, varscan2
- MAP7 | c.1780C>G p.Q594E | Missense Mutation (SNP) | VAF 72/673 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV63419777, COSV63420567; called by muse, mutect2, varscan2
- NIM1K | c.450G>T p.M150I | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.56); catalogued as COSV58142607; called by muse, mutect2, varscan2
- NOS1AP | c.1012C>A p.L338I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62636046, COSV62638800; called by muse, mutect2, varscan2
- NPC1L1 | c.436G>C p.G146R | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs778117861, COSV56926332; called by muse, varscan2
- NUP155 | c.3770G>C p.G1257A (on ENST00000231498 / NM_153485.3; = p.G1198A on NM_004298.4) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV51531091; called by muse, mutect2, varscan2
- OR5M8 | c.670A>G p.I224V | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs770196855, COSV59117179; called by muse, mutect2, varscan2
- PFKFB4 | c.1244G>A p.C415Y | Missense Mutation (SNP) | VAF 16/46 reads (35%) | PolyPhen probably damaging (0.961); catalogued as COSV51681492; called by muse, mutect2, varscan2
- RABGAP1 | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV58060450; called by muse, mutect2, varscan2
- RYR1 | c.4345G>A p.A1449T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV62100632; called by mutect2, varscan2
- SNN | c.227C>G p.A76G | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as COSV51600097; called by muse, mutect2, varscan2
- SSH1 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV58457226; called by muse, mutect2, varscan2
- ST6GAL2 | c.1518G>C p.K506N | Missense Mutation (SNP) | VAF 41/146 reads (28%) | PolyPhen possibly damaging (0.463); catalogued as COSV62416679, COSV62417066; called by muse, mutect2, varscan2
- SVOPL | c.913C>A p.L305M (on ENST00000419765; = p.L153M on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs201267104; called by muse, mutect2, varscan2
- TRIP11 | c.4654G>A p.A1552T | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); catalogued as COSV50927957; called by muse, varscan2
- WDR62 | c.1123T>G p.S375A | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV54336054, COSV54339958; called by muse, mutect2, varscan2
- YJU2 | c.16G>C p.V6L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV53606203, COSV53606638; called by muse, mutect2, varscan2
- FHDC1 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 11/237 reads (5%) | called by muse, mutect2
- GAREM1 | c.2008del p.D670Ifs*39 (on ENST00000269209 / NM_001242409.2; = p.D669Ifs*39 on NM_022751.3) | Frame Shift Del (DEL) | VAF 23/96 reads (24%) | called by mutect2, varscan2
- GAREM1 | c.2007del p.F669Lfs*40 (on ENST00000269209 / NM_001242409.2; = p.F668Lfs*40 on NM_022751.3) | Frame Shift Del (DEL) | VAF 27/122 reads (22%) | called by mutect2*, pindel, varscan2*
- IGLV5-37 | c.353G>C p.W118S | Missense Mutation (SNP) | VAF 72/408 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- IL37 | c.89C>A p.A30D | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2
- KLHL28 | c.31G>C p.A11P | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.207); called by muse, mutect2
- OSBPL7 | c.1682G>T p.G561V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- TES | c.550A>T p.S184C | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); called by muse, mutect2
- ZC3H13 | c.3240A>C p.E1080D | Missense Mutation (SNP) | VAF 63/650 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2
- ABCA10 | c.4065G>C p.L1355= | Silent (SNP) | VAF 63/420 reads (15%) | catalogued as COSV52223998; called by muse, mutect2, varscan2
- GPRC5C | c.1312C>A p.R438= (on ENST00000652232; = p.R393= on NM_018653.4) | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV61237410; called by muse, mutect2
- KIT | c.2355C>G p.S785= | Silent (SNP) | VAF 33/163 reads (20%) | catalogued as COSV55400128, COSV55405744; called by muse, mutect2, varscan2
- NEDD1 | c.672C>G p.T224= | Silent (SNP) | VAF 68/319 reads (21%) | catalogued as COSV57144147; called by muse, mutect2, varscan2
- NLRP3 | c.1173G>A p.R391= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as COSV60226236; called by muse, mutect2, varscan2
- PYCR2 | c.445C>T p.L149= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs139028833; called by mutect2, varscan2
- SIPA1L2 | c.4530C>T p.D1510= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs768861615, COSV53392476; called by muse, mutect2, varscan2
- TOP2A | c.2241A>G p.L747= | Silent (SNP) | VAF 39/1270 reads (3%) | called by muse, mutect2
- ABCC9 | chr12:21801149 C>G | 3'Flank (SNP) | VAF 56/261 reads (21%) | catalogued as COSV53975293; called by muse, varscan2
- IKBIP | c.297+7914G>T | Intron (SNP) | VAF 31/163 reads (19%) | called by muse, mutect2, varscan2
- IKBIP | c.297+7913A>T | Intron (SNP) | VAF 31/163 reads (19%) | called by muse, mutect2, varscan2
- LINC00173 | n.986C>T | RNA (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- NT5E | c.1360+440G>A | Intron (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
